Surgical pathology report (de-identified scan), TCGA case TCGA-42-2590, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-42-2590-01A (Primary Tumor).

[page 1 of 2]
SPECIMEN

- A. Omentum tumor
- B. Uterus, tubes, ovaries

CLINICAL NOTES

--

FROZEN SECTION DIAGNOSIS

Omentum, resection: Papillary serous carcinoma.

GROSS DESCRIPTION

- A. The specimen is received unfixed labeled "omentum tumor" and consists of a piece of white and red soft

tissue

measuring 19.5 x 11.5 x 4.5 cm. A portion of the specimen is taken for research purposes and a portion of the specimen is taken for frozen section diagnosis as requested. RS-4.

- B. The specimen is received unfixed labeled "uterus, tubes, ovaries" and consists of a pink uterus with

bilateral attached adnexa and other pieces of loose pink soft tissue

resembling tumor. The entire specimen weighs 162.7 gm. The uterus measures 8 x 5.5 x 3 cm. Both adnexa have a pink and tan granular appearance and the location of the ovaries is uncertain. Uterine tubes are identified. The right uterine tube is pink and measures

5

x 1 x 0.5 cm. The left uterine tube is 5 x 0.7 x 0.4 cm. The ectocervix is white and measures 3 x 2.5 cm with an external os measuring 0.7 x less than 0.1 cm. The uterus is opened with a single incision at the 3 o'clock position. The uterine cavity contains scant tan endometrium. The myometrium is 1.5 cm in thickness. There is some tissue within the left ovary measuring

1.5

cm in greatest dimension. The loose tissue with uterus that resembles loose tumor measures 8 x 6.5 x 2.5 cm in aggregate. A portion of the specimen is taken for research purposes. Additional sections after fixation. Blocks 1-4 - anterior cervix and endomyometrium; blocks 5-7 - posterior cervix and endomyometrium;

[page 2 of 2]
GROSS DESCRIPTION

blocks 8-10 - area of left ovary and uterine tube; blocks 11-13 - area of right ovary and uterine tube; blocks 14-16 - additional separate tumor.

MICROSCOPIC DESCRIPTION

A. Metastatic moderately differentiated papillary serous carcinoma is present.

B.

Tumor type: Papillary serous carcinoma

Tumor grade: FIGO grade 2 out of 3 (out of 3)

Tumor size: Carcinoma is present as multiple pieces of loose tumor. Some portions of tumor are present near portions of histologically normal ovary on both sides of the specimen.

Mitotic rate: 94 mitoses/10 HPFs (1 HPF = 0.19 sq mm)

Extracapsular tumor: Present

Uterine tube: Sections of the uterine tubes are unremarkable.

pTNM stage: T3c

3, 5, 14

DIAGNOSIS

A. Abdominal cavity, omentum, resection:

Metastatic moderately differentiated papillary serous carcinoma.

B. Uterus and bilateral adnexa, resection:

Cervix: Focal changes suggestive of HPV effect.

Endometrium: Inactive type endometrium with cystic change.

Myometrium: Leiomyoma.

Ovaries, right and left: Papillary serous carcinoma.

DIAGNOSIS

Parametrium: Papillary serous carcinoma.

Uterine tubes, right and left: No pathological diagnosis.

Source: NCI Genomic Data Commons file 11d9c124-a298-483a-a1e9-1d6af5b3d9bf (TCGA-42-2590.9C7C0209-B1D6-4174-B57E-E8BCD3E5D766.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).